Somatic mutation profile of tumor specimen 0E1KOF from CCDI case PBCWHY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1KOF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aadfe10-e414-490f-a6c7-ea965a44d6f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84127e44-aa82-4373-9a7d-42c5c6417bed

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 147/333 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1377476548, COSV99875125; called by muse, varscan2
- OR4P4 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58923029; called by muse, varscan2
- ALOX12 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 216/480 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); called by muse, varscan2
- HPRT1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 144/400 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, varscan2
- SMARCA4 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 148/349 reads (42%) | called by muse, varscan2
- TBC1D25 | c.1414A>T p.R472W | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- CTBP1 | c.195+65G>A | Intron (SNP) | VAF 51/107 reads (48%) | catalogued as rs1342687752; called by muse, varscan2
- GPC4 | c.-53G>A | 5'UTR (SNP) | VAF 35/68 reads (51%) | called by muse, varscan2
